Gene-level copy-number profile of tumor specimen ALCH-B2LT-TTP1-B from ALCHEMIST case ALCH-B2LT, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 64.9 years (23,700 days).
Specimen ALCH-B2LT-TTP1-B: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 828c3582-9802-443e-beb8-51afa831f02c.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2LT-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,731 have no estimate.
https://portal.gdc.cancer.gov/files/b70fc458-a18c-4d59-866f-fd81664f5367

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 350; copy number 1: 5,424; copy number 2: 31,397; copy number 3: 14,456; copy number 4: 4,981; copy number 5: 542; copy number 6: 1,196; copy number 7: 357; copy number 8: 87; copy number 9: 75; copy number 10: 9; copy number 12: 7; copy number 13: 10; copy number 14: 1.

Homozygous deletions (total copy number 0; autosomes only): 20 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:180,967,189–181,006,727, 4 genes: AC091874.2, AC091874.1, ARPP19P1, BTNL3.
- chr7:155,356,985–155,367,934, 1 gene: BLACE.
- chr10:80,207,372–80,254,121, 5 genes: LINC00857, RPS12P2, AL513174.1, EIF5AP4, AL359195.2.
- chr15:22,094,522–22,095,472, 1 gene (within-gene range 0–2): OR4N4.
- chr15:22,145,939–22,152,897, 2 genes: AC010760.1, RPS8P10.
- chr15:22,194,885–22,195,317, 1 gene: IGHV1OR15-4.
- chr19:1,107,637–1,228,431, 3 genes (within-gene range 0–1): SBNO2, STK11, HMGB2P1.
- chr22:50,735,825–50,745,339, 3 genes: AC000036.1, ACR, AC002056.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,284 genes in 30 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:54,641,754–54,888,850, 11 genes, copy number 5: MROH7, MROH7-TTC4, TTC4, PARS2, TTC22, AC096536.1, LEXM, DHCR24, AC096536.3, AC096536.2, DHCR24-DT.
- chr2:96,004,563–131,836,532, 696 genes, copy number 5–13 (broad region; genes not listed).
- chr2:132,262,328–133,596,399, 23 genes, copy number 8: CDC27P1, AC097532.1, ZNF806, AC097532.2, AC097532.3, FAM201B, RNU6-175P, GPR39, YBX1P7, RN7SKP103, LYPD1, AC010974.1, NCKAP5, AC010974.2, AC016909.1, NCKAP5-AS1, AC011755.1, NCKAP5-AS2, RNU6-579P, RN7SKP154, NCKAP5-IT1, AC011243.1, RN7SKP93.
- chr3:187,932,764–188,154,057, 6 genes, copy number 5 (within-gene range 4–5): AC068295.1, LINC01991, AC092941.1, AC092941.2, AC022498.1, LPP-AS2.
- chr6:97,710,953–97,717,197, 1 gene, copy number 6: AL080316.1.
- chr6:102,078,872–102,079,555, 1 gene, copy number 5: AP002530.1.
- chr6:103,583,135–125,749,190, 304 genes, copy number 6 (within-gene range 3–7) (broad region; genes not listed).
- chr6:125,747,664–133,895,553, 124 genes, copy number 5–14 (broad region; genes not listed).
- chr7:5,431,335–6,939,603, 55 genes, copy number 5: FBXL18, AC092171.2, MIR589, ACTB, AC006483.2, AC006483.1, FSCN1, RNF216, RNF216-IT1, MIR6874, ZNF815P, RN7SL556P, OCM, CCZ1, RSPH10B, PMS2, Y_RNA, AIMP2, SNORA80D, EIF2AK1, ANKRD61, RN7SL851P, RNU6-218P, AC004895.1, USP42, CYTH3, Y_RNA, FAM220A, AC009412.1, RPSAP73, RAC1, DAGLB, KDELR2, AC072052.1, GRID2IP, ZDHHC4, AC079742.1, C7orf26, ZNF853, ZNF316, AC073343.2, AC073343.1, ZNF12, PMS2CL, SPDYE20P, RSPH10B2, CCZ1B, OR7E39P, UNC93B2, OR7E136P, OR7E59P, AC079804.2, ALG1L5P, AC079804.1, FAM86LP.
- chr7:39,545,646–40,099,580, 18 genes, copy number 5: AC011290.1, YAE1, AC011290.2, AC004837.3, AC004837.1, RALA, AC004837.2, LINC00265, RNU6-719P, AC004987.3, CICP22, AC004987.2, AC004987.1, SSBL3P1, RWDD4P2, RN7SL496P, AC072061.1, CDK13.
- chr7:51,016,212–52,269,569, 11 genes, copy number 5 (within-gene range 3–5): COBL, RPL7L1P2, CICP17, AC012441.2, AC012441.1, AC005999.2, ROBO2P1, AC005999.1, RN7SL292P, AC079763.1, AC006320.1.
- chr7:84,995,553–95,544,542, 143 genes, copy number 5 (broad region; genes not listed).
- chr7:98,291,650–98,629,869, 6 genes, copy number 5 (within-gene range 3–5): BAIAP2L1, AC093799.1, RPS3AP26, PPIAP82, AC074121.1, NPTX2.
- chr7:99,616,946–100,968,347, 94 genes, copy number 5 (broad region; genes not listed).
- chr7:103,074,881–113,451,402, 138 genes, copy number 5–12 (broad region; genes not listed).
- chr10:50,623,466–50,727,969, 7 genes, copy number 5 (within-gene range 2–5): SGMS1-AS1, SHQ1P1, BEND3P1, NUTM2HP, AL589794.1, CTSLP4, PGGT1BP1.
- chr10:103,215,709–103,351,144, 5 genes, copy number 6: ST13P13, RPEL1, INA, PCGF6, RNU11-3P.
- chr11:72,836,745–73,142,318, 1 gene, copy number 5 (within-gene range 2–5): FCHSD2.
- chr11:73,157,946–73,181,724, 1 gene, copy number 5: AP002761.2.
- chr11:118,883,892–118,981,287, 8 genes, copy number 5: CXCR5, AP004609.1, BCL9L, MIR4492, UPK2, RN7SL688P, Y_RNA, FOXR1.
- chr11:129,761,713–129,814,690, 2 genes, copy number 5: AP003327.2, AP003327.1.
- chr12:38,078,529–39,539,851, 22 genes, copy number 5: AK6P2, CLUHP8, AC079460.1, AC079460.2, RNA5SP358, RNA5SP359, TUBB8P5, AC117372.1, NF1P12, Y_RNA, ALG10B, AC087897.1, AC087897.2, CPNE8, CPNE8-AS1, AC018448.2, AC018448.1, LINC02406, AC084373.1, KIF21A, AC121334.1, AC121334.2.
- chr14:18,667,249–18,712,643, 5 genes, copy number 5: CR383656.3, RPL22P20, CR383656.4, CR383656.2, NF1P10.
- chr14:18,967,434–19,131,167, 7 genes, copy number 5 (within-gene range 2–5): POTEM, AL929601.3, RNU6-1239P, AL589182.1, GRAMD4P4, DUXAP9, AL589182.3.
- chr15:20,003,840–20,003,862, 1 gene, copy number 5: IGHD5OR15-5A.
- chr15:22,160,431–22,160,868, 1 gene, copy number 7: IGHV1OR15-1.
- chr17:41,626,327–41,812,604, 9 genes, copy number 8: KRT42P, AC130686.1, EIF1, GAST, HAP1, RNA5SP442, RN7SL399P, JUP, P3H4.
- chr18:67,506,587–67,956,426, 10 genes, copy number 5: DSEL, AC110597.3, AC114689.3, AC022662.1, AC022655.1, FAM32DP, AC114689.1, LINC01903, AC114689.2, AC100844.1.
- chr19:36,259,540–47,515,091, 567 genes, copy number 6–9 (within-gene range 4–9) (broad region; genes not listed).
- chr22:23,738,682–23,839,128, 7 genes, copy number 5: ZNF70, VPREB3, C22orf15, CHCHD10, MMP11, SMARCB1, DERL3.

Autosomal genes at a single copy (total copy number 1): 2,927. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
